Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0FX, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0FX-TTP1-A (FFPE Scrolls).

[page 1 of 21]
AP Report
* Final Report *

Result type: AP Report
Result date: +30
Result status: Auth (Verified)
Result title: AP SPECIMEN DESCRIPTION
Performed by:
Encounter info:
Contributor system:

* Final Report *

Surgical Pathology Report

Patient Name: Pathology #: +30
Site/Client: Med. Rec. #: +31
Account #: Collected: +36
Location: Received:
DOB: Gender: M Reported:
Ordering Phy:
Order Number:

=====

FINAL PATHOLOGIC DIAGNOSES

SPECIMEN LABELED AS RECTAL MASS:

INVASIVE POORLY DIFFERENTIATED CARCINOMA, RECTUM. (BIOPSY)
PLEASE SEE COMMENTS.

COMMENTS: The following immunostains are performed. Their results are as follows:

AE1/AE3 : Positive
CK-20 : Positive
CDX-2 : Positive
CD-45(LCA) : Negative

Interpretation: The results of above immunostains and the H+T+E morphology of tumor are suggestive of primary rectal carcinoma, which is poorly differentiated .

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 21]
AP Report
* Final Report *

Electronically Signed Out

=====

SPECIMEN(S)
RECTAL MASS

PROCEDURE
ANOSCOPY WITH BIOPSY

PREOPERATIVE DIAGNOSIS
LOWER G I BLEED

POSTOPERATIVE DIAGNOSIS
RECTAL MASS

GROSS DESCRIPTION

Received in formalin labeled with the patient's name and identifiers, are two gray-tan, irregular, rubbery tissue fragments with adherent clotted blood, each measuring 1 x 0.6 x 0.5 cm and 1.2 x 0.7 x 0.6 cm. Both portions are inked black. All-two, as follows:

- 1- one portion of tissue trisected,
- 2- second portion of tissue trisected.

+31

This test was developed and its performance and characteristics determined by the [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing. Unless indicated as evaluated by gross examination only, all slides have been reviewed by the signing Pathologist.

+34

Completed Action List:

* Perform by [REDACTED]

* Order by [REDACTED]

Printed by:
Printed on:

[page 3 of 21]
CT-Abdomen/Pelvis W/W/O Contrast
* Final Report *

Result type: CT-Abdomen/Pelvis W/W/O Contrast
Result date: [REDACTED]
Result status: Modified +31
Result title: CT-Abdomen/Pelvis W/W/O Contrast
Performed by: [REDACTED]
Verified by: [REDACTED]
Encounter info: [REDACTED]

+31
+31
+31

*** Final Report ***

Document Contains Addenda

Reason For Exam
GI Bleed;Mass, Specify

Addendum (Verified)

The results (impression # 1, 2 and 3) and strong suspicion for malignancy was discussed with [REDACTED] over telephone at [REDACTED] with read back. I also brought [REDACTED] attention to my recommendation of evaluating the sigmoid colon.

+35

Signature Line

FINAL

Dictated By

And Verified By [REDACTED]

Electronically Signed Date: [REDACTED] +35

Date Dictated: [REDACTED]

"I certify that I personally viewed the images and performed the interpretation of this procedure"

CT Report
154.1

EXAM:
CT - Thorax, Abdomen and Pelvis with and without contrast

HISTORY:
[REDACTED] male with rectal mass

TECHNIQUE:
Contrast enhanced CT Scan of thorax, Abdomen and Pelvis done following administration of oral contrast and intravenous injection of 100 mL of Ultravist 300. No prior study for comparison

FINDINGS:

Printed by: [REDACTED]

Printed on: [REDACTED]

Page 1 of 3
(Continued)

[page 4 of 21]
THORAX:

Trachea and mainstem bronchi are patent. No significantly enlarged lymph node is seen in the mediastinum or hila. The great vessels of the mediastinum are unremarkable. Heart is mildly enlarged. There is no pericardial effusion.

Multiple areas of subsegmental atelectasis are seen in bilateral lung bases and right upper lobe. Minimal scarring is seen in the left upper lobe. No focal nodule or mass lesion is seen in the lungs. There is no pleural effusion.

ABDOMEN/PELVIS:

Concentric wall thickening with a mass-like appearance is seen involving the rectum and a canal. Soft tissue stranding and increased density is seen in the surrounding fat, consistent with infiltrations. There are multiple enlarged regional lymph nodes with a dominant lymph nodes seen at the level of L5 measuring approximately 17.5 x 14.5 mm (image 72/series 7). Another dominant lymph node measures approximately 22 x 18 mm (image 62/series 7). An approximately 4-5 cm long segment of proximal sigmoid colon reveals mild circumferential wall thickening without any associated regional lymphadenopathy. Moderate amount of fecal material is seen throughout colon. There is however no evidence of bowel obstruction. The small bowel loops are unremarkable. No significantly enlarged periaortic lymph node is seen in the retroperitoneum. There is no ascites.

The 12 mm hypodense lesion is seen in the left lobe of liver. Rest of the liver appears normal. Gall bladder is unremarkable. Intrahepatic bile ducts are not dilated.

Spleen is not enlarged. No adrenal mass is seen. The pancreas is unremarkable.

Bilateral kidneys are normal in morphology and reveals symmetric perfusion and excretion of contrast. No focal lesion or hydronephrosis is seen. Urinary bladder is over distended. There is however no associated wall thickening. The prostate is not enlarged.

Bones are grossly intact.

IMPRESSION:

- 1. Rectal mass with perirectal extension and enlarged regional lymph nodes. The findings are suggestive of malignancy.**
- 2. Mild circumferential wall thickening involving the proximal sigmoid colon. Recommended evaluation with colonoscopy to rule out synchronous neoplasm.**
- 3. Small hypodense lesion in the left lobe of the liver, too small to characterize. Metastasis is a possibility.**
- 4. Subsegmental atelectasis in both lungs. No evidence of pulmonary mass or nodule.**
- 5. Slightly over distended urinary bladder without associated wall thickening. Prostate is not enlarged.**

[page 5 of 21]
CT-Abdomen/Pelvis W/W/O Contrast
* Final Report *

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date: +31

Date Transcribed: +31

"I certify that I personally viewed the images and performed the interpretation of this procedure."

This document has an image

Completed Action List:

- * Order by
- * Perform b
- * Assist by
- * VERIFY by
- * Modify by

+
31

Printed by:

Printed on:

[page 6 of 21]
Trachea and mainstem bronchi are patent. No significantly enlarged lymph node is seen in the mediastinum or hila. The great vessels of the mediastinum are unremarkable. Heart is mildly enlarged. There is no pericardial effusion.

Multiple areas of subsegmental atelectasis are seen in bilateral lung bases and right upper lobe. Minimal scarring is seen in the left upper lobe. No focal nodule or mass lesion is seen in the lungs. There is no pleural effusion.

ABDOMEN/PELVIS:

Concentric wall thickening with a mass-like appearance is seen involving the rectum and a canal. Soft tissue stranding and increased density is seen in the surrounding fat, consistent with infiltrations. There are multiple enlarged regional lymph nodes with a dominant lymph nodes seen at the level of L5 measuring approximately 17.5 x 14.5 mm (image 72/series 7). Another dominant lymph node measures approximately 22 x 18 mm (image 62/series 7). An approximately 4-5 cm long segment of proximal sigmoid colon reveals mild circumferential wall thickening without any associated regional lymphadenopathy. Moderate amount of fecal material is seen throughout colon. There is however no evidence of bowel obstruction. The small bowel loops are unremarkable. No significantly enlarged periaortic lymph node is seen in the retroperitoneum. There is no ascites.

The 12 mm hypodense lesion is seen in the left lobe of liver. Rest of the liver appears normal. Gall bladder is unremarkable. Intrahepatic bile ducts are not dilated.

Spleen is not enlarged. No adrenal mass is seen. The pancreas is unremarkable.

Bilateral kidneys are normal in morphology and reveals symmetric perfusion and excretion of contrast. No focal lesion or hydronephrosis is seen. Urinary bladder is over distended. There is however no associated wall thickening. The prostate is not enlarged.

Bones are grossly intact.

IMPRESSION:

1. Rectal mass with perirectal extension and enlarged regional lymph nodes. The findings are suggestive of malignancy.
2. Mild circumferential wall thickening involving the proximal sigmoid colon. Recommended evaluation with colonoscopy to rule out synchronous neoplasm.
3. Small hypodense lesion in the left lobe of the liver, too small to characterize. Metastasis is a possibility.
4. Subsegmental atelectasis in both lungs. No evidence of pulmonary mass or nodule.
5. Slightly over distended urinary bladder without associated wall thickening. Prostate is not enlarged.

[page 7 of 21]
CT-Thorax (W/W/O Contrast)

Result type: CT-Thorax (W/W/O Contrast)
Result date: [REDACTED] +31
Result status: Modified
Result title: CT-Thorax (W/W/O Contrast)
Performed by: [REDACTED] +31
Verified by: [REDACTED] +31
Encounter info: [REDACTED] +31

Document Contains Addenda

Reason For Exam
SOB (dyspnea)

Addendum (Verified)

The results (impression # 1, 2 and 3) and strong suspicion for malignancy was discussed with [REDACTED] over telephone at [REDACTED] with read back. I also brought [REDACTED] attention to my recommendation of evaluating the sigmoid colon. +35

Signature Line

FINAL

Dictated By

And Verified By: [REDACTED]

Electronically Signed Date: [REDACTED] +35

Date Dictated: [REDACTED] +35

"I certify that I personally viewed the images and performed the interpretation of this procedure"

CT Report

154.1

EXAM:

CT - Thorax, Abdomen and Pelvis with and without contrast

HISTORY:

[REDACTED] male with rectal mass

TECHNIQUE:

Contrast enhanced CT Scan of thorax, Abdomen and Pelvis done following administration of oral contrast and intravenous injection of 100 mL of Ultravist 300. No prior study for comparison

FINDINGS:

THORAX:

Printed by:

Printed on:

[page 8 of 21]
CT-Thorax (W/W/O Contrast)

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date: +31

Date Transcribed: +31

"I certify that I personally viewed the images and performed the interpretation of this procedure."

This document has an image

Completed Action List:

* Order by

* Perform

* Assist by

* VERIFY by

* Modify by

+31

Printed by:

Printed on:

[page 9 of 21]
PET/CT-Imaging-Skull to Thigh

* Final Report *

Result type: PET/CT-Imaging-Skull to Thigh

Result date:

Result status:

Result title:

Performed by:

Verified by:

Encounter info:

+272

+272

+272

+272

* Final Report *

Reason For Exam
RECTAL CANCER

PE Report
154.9

EXAM: PET CT TUMOR IMAGING

HISTORY:

Rectal cancer restaging study.

TECHNIQUE:

The patient received 9.33 mCi of 18-fluoro-2-deoxyglucose (F-18 FDG) intravenously, at blood glucose level of 106 mg/dL. After approximately one hour post injection of the tracer, sequential low-dose CT without intravenous contrast enhancement and positron emission tomography (PET) were performed from the base of the skull to proximal thighs. The registered, noncontrast-enhanced CT, nonattenuation-corrected PET and attenuation-corrected PET images were acquired and reconstructed into axial, coronal and sagittal projections for interpretation.

Please note that the CT portion of the present study was performed for attenuation correction and for anatomic localization of the findings in the PET images only, which did not employ diagnostic dose and collimation, intravenous contrast and breath-holding techniques. Prior to imaging, the patient was given 450 mL of oral contrast to help visualization of the alimentary tract. This report is an interpretation of functional PET imaging of glucose metabolism by Nuclear Medicine physicians. A referral to a Radiologist should be made if a diagnostic CT is required.

COMPARISON:

PET/CT scan from [REDACTED] +62

FINDINGS:

A few FDG avid enlarged lymph nodes are seen in the right external iliac region, larger of which measuring approximately 2.1 x 3.2 cm, with a maximal SUV of 19.4. A few FDG avid right external iliac lymph nodes are also seen with the largest of which measuring approximately 2.2 x 2.9 cm, with a maximal SUV of 21.9.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 10 of 21]
PET/CT-Imaging-Skull to Thigh

* Final Report *

A small FDG avid lymph node is noted in the suprasternal notch, measuring approximately 1.0 cm, with a maximal SUV of 3.8. No focal increased FDG uptake is noted in the mediastinum or lungs to suggest malignancy.

Diffuse mild increased FDG uptake is noted in the bone marrow of axial and proximal appendicular skeleton, as well as in the spleen, likely reactive in nature due to recent administration of recent chemotherapy. Increased FDG uptake is also noted in the thymic tissue, likely related to thymic rebound after chemotherapy.

IMPRESSION:

1. FDG avid lymphadenopathy involving the right external iliac and inguinal region; likely represent rectal cancer metastasis.
2. FDG avid small suprasternal lymph node, suspicious for metastasis.

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date: +272

Date Transcribed:

"I certify that I personally viewed the images and performed the interpretation of this procedure."

This document has an image

Completed Action List:

* Order by

* Perform

* Assist by

* VERIFY by

Printed by:

Printed on:

[page 11 of 21]
CT-Abdomen/Pelvis W/Contrast
* Final Report *

Result type: CT-Abdomen/Pelvis W/Contrast
Result date: [REDACTED] +328
Result status: Modified
Performed by: [REDACTED] +328
Verified by: [REDACTED]
Encounter info: [REDACTED]

*** Final Report ***

Reason For Exam
RECTAL CA

CT Report
DATE: [REDACTED] +328

READING LOCATION: [REDACTED]

EXAM: CT ABDOMEN AND PELVIS WITH CONTRAST

CLINICAL HISTORY: Rectal cancer, lymph node metastases.
+272

COMPARISON: PET scan [REDACTED] and earlier studies.

TECHNIQUE: CT of the abdomen and pelvis was performed following intravenous and enteric contrast administration.

FINDINGS: A right external iliac lymph node which was enlarged and FDG avid on a recent PET scan is no longer seen. There are adjacent subcentimeter right inguinal nodes which have returned to a normal size. These are about 0.9 cm short axis each and had been nearly 2 cm. No abnormally enlarged by criteria abdominal, retroperitoneal, mesenteric, pelvic or inguinal nodes at this time.

The liver is stable with no evidence of metastatic disease. No biliary dilatation. The gallbladder, pancreas, spleen and adrenal glands are unremarkable. The kidneys and bladder are stable. No hydronephrosis.

Colostomy in right lower quadrant. No abnormally thick-walled or abnormally dilated bowel segment. No ascites. No bone lesion.

IMPRESSION:

Right external iliac lymph node resolved and right inguinal nodes have returned to a normal size. No adenopathy at this time. No evidence for metastatic disease.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 12 of 21]
Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date +329

Date Transcribed: +328

"I certify that I personally viewed the images and performed the interpretation of this procedure."

This document has an image

Completed Action List:

- * Order by +307
- * Perform b +328
- * Assist by +328
- * VERIFY by +329

Printed by:

Printed on:

[page 13 of 21]
CT-Abdomen/Pelvis W/Contrast

* Final Report *

Result type: CT-Abdomen/Pelvis W/Contrast
Result date: [REDACTED] +1931
Result status: Auth (Verified)
Result title: CT-Abdomen/Pelvis W/Contrast
Performed by: [REDACTED]
Verified by: [REDACTED]
Encounter info: [REDACTED]

*** Final Report ***

Reason For Exam

Colon Cancer

CT Report

LOCATION: [REDACTED]

EXAM DATE: [REDACTED] +1931

EXAM DESCRIPTION: CT-Thorax (W/Contrast); CT-Abdomen/Pelvis W/Contrast

INDICATION: Treated rectal cancer, surveillance.

COMPARISON: [REDACTED] +1644

CONTRAST: 100 cc Visipaque 320 given intravenously.

TECHNIQUE: Post-contrast images through the chest and abdomen were obtained, followed by delayed phase images through the abdomen and pelvis at 5 mm axial slice thickness. Coronal and sagittal reformatted images were provided. Images in lung windows and lung MIPS were also reviewed.

FINDINGS: CHEST:

Lower neck/thyroid: Unremarkable.

Lungs: Mild mosaic attenuation appearance of the lungs could relate to some degree of air trapping; this was present previously. No discrete pulmonary nodules identified.

Central airway: Unremarkable.

Pleura: No pleural effusion, thickening, or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: No coronary arterial calcification. Unremarkable cardiac morphology and pericardium.

Printed by: [REDACTED]

Printed on: [REDACTED]

[page 14 of 21]
CT-Abdomen/Pelvis W/Contrast

* Final Report *

Lymph nodes: No enlarged thoracic lymph nodes.

Mediastinum: Unremarkable.

Thoracic spine and chest wall: Preserved thoracic vertebral body height, with no aggressive osseous lesions.

Other Lines/Tubes/Devices/Hardware: There is a right chest wall port with catheter tip in the mid to upper SVC.

ABDOMEN/PELVIS:

A 9 mm low-attenuation focus in the left hepatic lobe in series 301, image 47 is unchanged and too small to characterize. Otherwise, the liver, spleen, pancreas, and adrenal glands are unremarkable. The gallbladder is present with no biliary ductal dilatation.

An 8 mm right renal low-attenuation lesion in series 401, image 35 is unchanged and too small to characterize. There is mildly heterogeneous renal perfusion, with some areas demonstrating lower enhancement compared to others, for example in the interpolar right kidney in series 402, image 60 and the left renal lower pole in the same image.

The abdominal aorta is nonaneurysmal with minimal atherosclerotic calcification. Two adjacent nonenlarged left periaortic nodes abut one another in series 301, image 71 measuring 1.2 x 0.8 in aggregate, similar to prior. No enlarged abdominal or pelvic lymph nodes or fluid collections.

The small and large bowel are normal in caliber with no obstruction or adjacent inflammation. There is a right lower quadrant loop ileostomy.

There are two large calculi in the urinary bladder, one of which measures 3.5 x 3.1 cm and the other 3.0 x 1.5 cm. The urinary bladder is otherwise unremarkable in appearance and the prostate gland nonenlarged.

Preserved lumbar vertebral body height, with no aggressive osseous lesions.

IMPRESSION: 1. No evidence of recurrent or metastatic disease in the chest, abdomen, and pelvis.

2. There are two large urinary bladder calculi as before.

3. There are heterogeneous areas of renal perfusion, with some areas relatively wedge-shaped and hypoenhancing compared to others. This is nonspecific, but the appearance can be seen in pyelonephritis; correlate clinically.

Automated exposure control for dose reduction was used.

Technical parameters are automatically adjusted ALARA based on the patients size.

Use of iterative reconstruction technique for dose reduction was used.

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date:

Date Transcribed:

+1931

+1931

Printed by:

Printed on:

[page 15 of 21]
CT-Abdomen/Pelvis W/Contrast

* Final Report *

"I certify that I personally viewed the images and performed the interpretation of this procedure."

This document has an image

Completed Action List:

* Order by	+1924
* Perform	+1931
* Assist b	+1931
* VERIFY b	+1932

Printed by:
Printed on:

Page 3 of 3
(End of Report)

[page 16 of 21]
CT-Thorax (W/Contrast)

Result type: CT-Thorax (W/Contrast)
Result date: [REDACTED] +1921
Result status: Auth (Verified)
Result title: CT-Thorax (W/Contrast)
Performed by: [REDACTED] +1922
Verified by: [REDACTED] +1922
Encounter info: [REDACTED]

Reason For Exam
Colon Cancer

CT Report

LOCATION: [REDACTED]

EXAM DATE: [REDACTED] +1931

EXAM DESCRIPTION: CT-Thorax (W/Contrast); CT-Abdomen/Pelvis W/Contrast

INDICATION: Treated rectal cancer, surveillance.

COMPARISON: [REDACTED] +1644

CONTRAST: 100 cc Visipaque 320 given intravenously.

TECHNIQUE: Post-contrast images through the chest and abdomen were obtained, followed by delayed phase images through the abdomen and pelvis at 5 mm axial slice thickness. Coronal and sagittal reformatted images were provided. Images in lung windows and lung MIPS were also reviewed.

FINDINGS: CHEST:

Lower neck/thyroid: Unremarkable.

Lungs: Mild mosaic attenuation appearance of the lungs could relate to some degree of air trapping; this was present previously. No discrete pulmonary nodules identified.

Central airway: Unremarkable.

Pleura: No pleural effusion, thickening, or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: No coronary arterial calcification. Unremarkable cardiac morphology and pericardium.

Lymph nodes: No enlarged thoracic lymph nodes.

Mediastinum: Unremarkable.

Printed by: [REDACTED]

Printed on: [REDACTED]

[page 17 of 21]
CT-Thorax (W/Contrast)

Thoracic spine and chest wall: Preserved thoracic vertebral body height, with no aggressive osseous lesions.

Other Lines/Tubes/Devices/Hardware: There is a right chest wall port with catheter tip in the mid to upper SVC.

ABDOMEN/PELVIS:

A 9 mm low-attenuation focus in the left hepatic lobe in series 301, image 47 is unchanged and too small to characterize. Otherwise, the liver, spleen, pancreas, and adrenal glands are unremarkable. The gallbladder is present with no biliary ductal dilatation.

An 8 mm right renal low-attenuation lesion in series 401, image 35 is unchanged and too small to characterize. There is mildly heterogeneous renal perfusion, with some areas demonstrating lower enhancement compared to others, for example in the interpolar right kidney in series 402, image 60 and the left renal lower pole in the same image.

The abdominal aorta is nonaneurysmal with minimal atherosclerotic calcification. Two adjacent nonenlarged left periaortic nodes abut one another in series 301, image 71 measuring 1.2 x 0.8 in aggregate, similar to prior. No enlarged abdominal or pelvic lymph nodes or fluid collections.

The small and large bowel are normal in caliber with no obstruction or adjacent inflammation. There is a right lower quadrant loop ileostomy.

There are two large calculi in the urinary bladder, one of which measures 3.5 x 3.1 cm and the other 3.0 x 1.5 cm. The urinary bladder is otherwise unremarkable in appearance and the prostate gland nonenlarged.

Preserved lumbar vertebral body height, with no aggressive osseous lesions.

IMPRESSION: 1. No evidence of recurrent or metastatic disease in the chest, abdomen, and pelvis.

2. There are two large urinary bladder calculi as before.

3. There are heterogeneous areas of renal perfusion, with some areas relatively wedge-shaped and hypoenhancing compared to others. This is nonspecific, but the appearance can be seen in pyelonephritis; correlate clinically.

Automated exposure control for dose reduction was used.

Technical parameters are automatically adjusted ALARA based on the patients size.

Use of iterative reconstruction technique for dose reduction was used.

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date:

+1932

Date Transcribed:

+1932

"I certify that I personally viewed the images and performed the interpretation of this procedure."

Printed by:

Printed on:

[page 18 of 21]
CT-Thorax (W/Contrast)

This document has an image

Completed Action List:

- * Order by
- * Perform b
- * Assist by
- * VERIFY by

+1924

+1931

+1931

+1932

Printed by:
Printed on:

Page 3 of 3
(End of Report)

[page 19 of 21]
██████████ First available imaging is post start of therapy that lead to exceptional response
(BL = date of baseline imaging compared to date of first therapy that led to exceptional response.
For this case, no imaging was available before nor at the time of this first therapy. Therefore, there is no true
BL imaging)

[page 20 of 21]
Level 1 case

Axial, coronal, and sagittal CT images: 1st available images (upper row),
LT pelvic LN – wide yellow arrow, rectal cancer – small orange arrows

10 months = 328 days later (middle row), post operative, post colostomy, no local recurrence of tumor

5 years = 1931 days later (lower row), post colostomy, post chemotherapy, no local recurrence of tumor

[page 21 of 21]
Level 1 case

Axial and coronal (RT) CT images: 1st available images
LT image: LT pelvic LN – 10 x 14 mm
Center and RT images: rectal cancer – 39 x 48 x 97 mm

Source: NCI Genomic Data Commons file 4921bad8-0384-46d1-bf33-d8498db6909b (ER0483 ER-B0FX Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).